Somatic mutation profile of tumor specimen MP2PRT-PARIPB-TMP1-B (aliquot MP2PRT-PARIPB-TMP1-B-1-0-D-A834-36) from MP2PRT case MP2PRT-PARIPB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,017 days).
Specimen MP2PRT-PARIPB-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c5fb974-ab94-4f61-a061-a4eb55e425f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARIPB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARIPB-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd92983d-4eed-488c-a246-36ef66d598e3

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Nonsense Mutation 2, In Frame Del 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HLA-DOB | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 84/305 reads (28%) | catalogued as rs113536280; called by muse, mutect2, varscan2
- LGI1 | c.1478del p.G493Efs*20 | Frame Shift Del (DEL) | VAF 38/128 reads (30%) | catalogued as CM105511; called by pindel, varscan2
- LRP1 | c.10072G>A p.D3358N | Missense Mutation (SNP) | VAF 30/488 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1473290940; called by muse, mutect2
- MIPEP | c.1892G>A p.R631K | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101193086; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 51/500 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4K5 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs201033872, COSV100262636; called by muse, varscan2
- ARHGAP42 | c.2410C>G p.Q804E | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.096); called by muse, mutect2
- FREM3 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 44/401 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GLS | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- OLIG2 | c.435_470del p.K145_R156del | In Frame Del (DEL) | VAF 3/30 reads (10%) | called by mutect2*, pindel
- PRDM14 | c.441_485del p.D147_P161del | In Frame Del (DEL) | VAF 3/24 reads (13%) | called by mutect2*, pindel
- SP6 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 69/636 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.081); called by muse, varscan2
- ZSCAN12 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 63/254 reads (25%) | called by muse, varscan2
- CALML3 | c.294C>T p.N98= | Silent (SNP) | VAF 216/641 reads (34%) | catalogued as rs1380059416, COSV59449530; called by muse, varscan2
- MMS22L | c.2589C>T p.L863= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- NID1 | c.2706C>T p.D902= | Silent (SNP) | VAF 43/770 reads (6%) | catalogued as rs1264100851, COSV99938143; called by muse, mutect2
- SLC26A1 | c.1656C>T p.D552= | Silent (SNP) | VAF 244/686 reads (36%) | called by muse, varscan2
- TBC1D15 | c.480C>G p.L160= | Silent (SNP) | VAF 79/319 reads (25%) | catalogued as COSV100041713; called by muse, varscan2
- ZNF100 | c.987C>T p.S329= | Silent (SNP) | VAF 71/244 reads (29%) | catalogued as rs776375744; called by muse, mutect2, varscan2
- THBS3 | c.1548+66C>G | Intron (SNP) | VAF 134/398 reads (34%) | called by muse, varscan2
